Somatic mutation profile of tumor specimen TCGA-OR-A5KW-01A (aliquot TCGA-OR-A5KW-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KW, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 55.7 years (20,328 days).
Specimen TCGA-OR-A5KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 100fd21c-d75e-47f8-9565-0390474cb178.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KW-10A (Blood Derived Normal), aliquot TCGA-OR-A5KW-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6121c026-1f8c-4a7c-aaa6-33daa34e8604

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Nonsense Mutation 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.951C>G p.Y317* | Nonsense Mutation (SNP) | VAF 213/250 reads (85%) | catalogued as rs386134260, CM970934, CM981270, COSV53647081; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- FLNC | c.7449C>G p.N2483K | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57956594; called by muse, mutect2, varscan2
- FXR1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 153/178 reads (86%) | catalogued as COSV99976726; called by muse, mutect2, varscan2
- HEXB | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs747152494; called by muse, varscan2
- IGHV3-43 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.038); catalogued as rs1217147095; called by muse, mutect2, varscan2
- ITGB6 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs766195598; called by muse, mutect2
- ITIH1 | c.1544T>C p.I515T | Missense Mutation (SNP) | VAF 109/121 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1447574116; called by muse, mutect2, varscan2
- JAG2 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 109/389 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59308616; called by muse, mutect2, varscan2
- PCDHB9 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 104/243 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as rs782120289, COSV53380624; called by muse, mutect2, varscan2
- SCRN2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 104/116 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552628767; called by muse, mutect2, varscan2
- SETDB2 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs751136767; called by muse, mutect2, varscan2
- BLOC1S5 | c.196-2A>T p.X66_splice | Splice Site (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- CNBD2 | c.1580C>T p.P527L (on ENST00000373973 / NM_001365709.1; = p.P523L on NM_080834.4) | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KEL | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCTL | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.623); called by muse, mutect2
- POM121L12 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RFPL1 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 123/173 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZBTB10 | c.921_923del p.L308del | In Frame Del (DEL) | VAF 31/57 reads (54%) | called by pindel, varscan2
- ZNF157 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 169/350 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- C1orf127 | c.1707G>T p.G569= | Silent (SNP) | VAF 71/86 reads (83%) | called by muse, mutect2, varscan2
- CMTM1 | c.15C>T p.H5= | Silent (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2
- DOCK10 | c.2787G>C p.L929= | Silent (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2, varscan2
- DSG2 | c.591C>G p.S197= | Silent (SNP) | VAF 63/75 reads (84%) | catalogued as rs1254964767; called by muse, mutect2, varscan2
- ELSPBP1 | c.564T>C p.Y188= | Silent (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- FOXG1 | c.1284G>A p.S428= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV57398869; called by muse, mutect2, varscan2
- MAGEA12 | c.435C>T p.D145= | Silent (SNP) | VAF 40/538 reads (7%) | called by muse, mutect2
- SFTPD | c.27G>T p.L9= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- ZNF808 | c.2544A>G p.K848= | Silent (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
